Somatic mutation profile of tumor specimen TCGA-FV-A2QQ-01A (aliquot TCGA-FV-A2QQ-01A-11D-A22F-10) from TCGA case TCGA-FV-A2QQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.4 years (29,354 days).
Specimen TCGA-FV-A2QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9de37d10-cf22-47c8-b4e7-61bd00d4009d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A2QQ-10B (Blood Derived Normal), aliquot TCGA-FV-A2QQ-10B-01D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85812859-c3c7-42c8-a1aa-2bd8421a9fea

The open-access MAF lists 155 somatic variants for this specimen: 105 protein-altering or splice-affecting, 37 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 37, Frame Shift Del 7, Nonsense Mutation 5, Intron 4, 3'UTR 4, Splice Region 3, 5'UTR 2, Frame Shift Ins 2, RNA 2, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>G p.N387K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62688055, COSV62689041; called by muse, mutect2, varscan2
- ACAT2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1268066667, COSV58458284; called by muse, mutect2, varscan2
- ADAMTS13 | c.1454A>G p.H485R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV63020921; called by muse, mutect2, varscan2
- ADCY8 | c.797T>G p.L266R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as COSV53900234, COSV53903941; called by muse, mutect2, varscan2
- AFMID | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV56959297; called by muse, mutect2, varscan2
- ALB | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV55737444; called by muse, mutect2, varscan2
- ALLC | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52993934; called by muse, mutect2, varscan2
- ANKRD34A | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV60160743; called by muse, mutect2, varscan2
- AP2A1 | c.2650C>T p.L884F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs746056839, COSV58241231; called by muse, mutect2, varscan2
- ARMC2 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52900169; called by muse, mutect2, varscan2
- BCAN | c.2465C>A p.P822H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV61256412; called by muse, mutect2, varscan2
- BUB1 | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV57062804; called by muse, mutect2, varscan2
- CA9 | c.332A>C p.E111A | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65675486; called by muse, mutect2, varscan2
- CARD18 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as COSV73233164; called by muse, mutect2, varscan2
- CCDC66 | c.169A>G p.T57A (on ENST00000394672 / NM_001353147.1; = p.T23A on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as rs1340950828, COSV58303076; called by muse, mutect2, varscan2
- CDC20B | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1373181109, COSV57051404; called by muse, mutect2, varscan2
- CHL1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as rs1227512880, COSV56590980, COSV56598719; called by muse, mutect2, varscan2
- CHSY3 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59273831; called by muse, mutect2, varscan2
- CLEC9A | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV63349985; called by muse, mutect2, varscan2
- CNDP2 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60838997; called by muse, mutect2, varscan2
- CNGB3 | c.1181A>C p.Y394S | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV60688118; called by muse, mutect2, varscan2
- COL7A1 | c.6136G>A p.G2046S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM154130, COSV60394119; called by muse, mutect2, varscan2
- CRIP3 | c.400+5_400+8del | Splice Region (DEL) | VAF 10/54 reads (19%) | catalogued as rs761139953; called by pindel, varscan2
- CSMD1 | c.4918C>A p.P1640T (on ENST00000520002; = p.P1639T on NM_033225.6) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59308966, COSV59358428; called by muse, mutect2, varscan2
- CSPG4 | c.5143G>A p.V1715I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as rs1255928590, COSV57893576; called by muse, mutect2, varscan2
- CTR9 | c.3077T>A p.L1026H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as COSV63728363; called by muse, mutect2, varscan2
- DAOA | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.55); catalogued as rs1490907366, COSV61602144; called by muse, mutect2, varscan2
- DCD | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.998); catalogued as COSV53201457; called by muse, mutect2, varscan2
- DDX10 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59433610; called by muse, mutect2, varscan2
- DST | c.20651G>C p.C6884S (on ENST00000361203 / NM_001374722.1; = p.C4581S on NM_015548.5) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as COSV55008778; called by muse, mutect2, varscan2
- FAM71A | c.1133C>A p.T378N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV54235348, COSV99674619; called by muse, mutect2, varscan2
- FBLN1 | c.1604A>G p.N535S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); catalogued as COSV53045982; called by muse, mutect2, varscan2
- FBXL7 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs745453041; called by mutect2, varscan2
- FEM1A | c.1049A>C p.Y350S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV54163510; called by muse, mutect2, varscan2
- FILIP1 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1226651077, COSV52727294; called by muse, mutect2, varscan2
- FLNC | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs200215340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRAS1 | c.7759G>T p.V2587F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53603825; called by muse, mutect2, varscan2
- GLRA1 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV51010555; called by muse, mutect2, varscan2
- GOLGA4 | c.4061C>A p.A1354D | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV62710285; called by muse, mutect2, varscan2
- HCN1 | c.1341A>T p.E447D | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57504342; called by muse, mutect2, varscan2
- HHAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs143700139; called by muse, mutect2, varscan2
- IQCE | c.1901C>G p.T634S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV58077691; called by muse, mutect2
- ITGB5 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV56148259; called by muse, mutect2, varscan2
- KCNE3 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59551772; called by muse, mutect2, varscan2
- LRATD2 | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV59230001; called by muse, mutect2
- LRBA | c.4265C>T p.S1422F | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63953202; called by muse, mutect2, varscan2
- LRFN5 | c.1125T>G p.I375M | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as COSV53251827; called by muse, mutect2, varscan2
- LRP1B | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV67206525, COSV67207425, COSV67219908; called by muse, mutect2, varscan2
- MAP3K1 | c.3124C>G p.L1042V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV68123037; called by muse, mutect2, varscan2
- ME2 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV58422877; called by muse, mutect2, varscan2
- MYO3A | c.2508C>A p.V836= | Splice Region (SNP) | VAF 13/102 reads (13%) | catalogued as COSV56327103, COSV56347651; called by muse, mutect2, varscan2
- MYO3A | c.4391A>G p.H1464R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV56327114; called by muse, mutect2, varscan2
- NAV3 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV57074173; called by muse, mutect2, varscan2
- NLRP7 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV60173165; called by muse, mutect2, varscan2
- OR2A12 | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs1443089210, COSV68821281; called by muse, mutect2, varscan2
- OR6P1 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV58108537; called by muse, mutect2
- PGR | c.510C>G p.C170W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV54799808; called by muse, mutect2, varscan2
- PTPRN2 | c.2655C>G p.F885L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66104732; called by muse, mutect2, varscan2
- RAB23 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.632); catalogued as COSV58097730; called by muse, mutect2, varscan2
- RASGRF1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs950690194, COSV67249476; called by muse, mutect2, varscan2
- RELN | c.7756A>T p.T2586S | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58996516; called by muse, mutect2, varscan2
- RGS16 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs753151197, COSV62375634; called by muse, mutect2, varscan2
- RNF180 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747322087, COSV56961320; called by muse, mutect2, varscan2
- RPL5 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs200315052, COSV59873342; called by muse, mutect2, varscan2
- RPRM | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV57988686; called by muse, mutect2, varscan2
- RUFY1 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV60159371; called by muse, mutect2, varscan2
- SELE | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as COSV60974929; called by muse, mutect2, varscan2
- SFT2D2 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54798880, COSV99608259; called by muse, mutect2, varscan2
- SH3BP5L | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs777717782, COSV63539037; called by muse, mutect2
- SHC2 | c.785A>G p.D262G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52745200; called by muse, mutect2, varscan2
- SLC16A12 | c.1313G>T p.S438I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV57949102; called by muse, mutect2, varscan2
- SLC39A12 | c.1883G>A p.C628Y (on ENST00000377369 / NM_001145195.2; = p.C591Y on NM_152725.3) | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.699); catalogued as COSV66197261, COSV66199842, COSV66202649; called by muse, mutect2, varscan2
- SNTA1 | c.909G>A p.Q303= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as COSV54128897; called by muse, mutect2, varscan2
- SPTA1 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63751691; called by muse, mutect2, varscan2
- SRRM5 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56193230; called by muse, mutect2, varscan2
- STAT4 | c.940A>G p.N314D | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV61829178; called by muse, mutect2, varscan2
- TAS2R1 | c.868A>T p.K290* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV66778069, COSV66778422; called by muse, mutect2, varscan2
- TBC1D9B | c.1411A>T p.K471* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as COSV62281645; called by muse, mutect2, varscan2
- TDRD9 | c.3826G>A p.V1276I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs182776644, COSV59142364; called by muse, mutect2, varscan2
- TMEM106C | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1565658340, COSV56742642; called by muse, mutect2, varscan2
- TPPP3 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs146906089; called by muse, mutect2, varscan2
- TROAP | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57743644; called by muse, mutect2, varscan2
- TTN | c.69842G>C p.R23281T (on ENST00000591111; = p.R15857T on NM_003319.4) | Missense Mutation (SNP) | VAF 46/165 reads (28%) | PolyPhen benign (0.001); catalogued as COSV59991639; called by muse, mutect2, varscan2
- TTN | c.7862C>A p.A2621D (on ENST00000591111; = p.A2575D on NM_003319.4) | Missense Mutation (SNP) | VAF 16/115 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs753441258, COSV59981613, COSV59991676; called by muse, mutect2, varscan2
- VAX1 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53329262; called by muse, mutect2, varscan2
- WDFY4 | c.7745C>A p.S2582* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55426504; called by muse, mutect2, varscan2
- ZMYND12 | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 37/86 reads (43%) | catalogued as COSV65341884; called by muse, mutect2, varscan2
- ZNF350 | c.911A>C p.N304T | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV54708440; called by muse, mutect2, varscan2
- ZNF578 | c.1345C>A p.H449N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101404990, COSV69736333; called by muse, mutect2, varscan2
- ZNF626 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74129297; called by muse, mutect2, varscan2
- ZNF827 | c.2668G>A p.G890R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65226273; called by muse, mutect2, varscan2
- APOB | c.7615del p.V2539* | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel, varscan2
- ATXN7L2 | c.416del p.P139Qfs*107 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | called by mutect2, pindel, varscan2
- BIRC7 | c.82del p.E28Sfs*13 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- CDH9 | c.2094dup p.Q699Sfs*13 | Frame Shift Ins (INS) | VAF 43/168 reads (26%) | called by mutect2, pindel, varscan2
- CNDP2 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CORO6 | c.896_897del p.E299Afs*33 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- CTSB | c.590del p.P197Hfs*78 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- FCGBP | c.4822C>T p.Q1608* | Nonsense Mutation (SNP) | VAF 124/568 reads (22%) | called by muse, mutect2, varscan2
- FIGN | c.861dup p.T288Hfs*79 | Frame Shift Ins (INS) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- IFT140 | c.1299del p.T434Rfs*54 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- NBPF11 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 65/591 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PRAMEF14 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF488 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNRF3 | c.1703_1704del p.V568Gfs*5 (on ENST00000544604 / NM_001206998.2; = p.V468Gfs*5 on NM_032173.3) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- ATN1 | c.2760C>T p.V920= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63110752; called by muse, mutect2, varscan2
- CACNG7 | c.708G>A p.A236= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV55813930; called by muse, mutect2, varscan2
- CCDC71 | c.1272G>T p.L424= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV58910026; called by muse, mutect2, varscan2
- CD81 | c.642G>T p.V214= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV55132724; called by muse, mutect2, varscan2
- CDH18 | c.2241T>G p.A747= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as COSV56915190; called by muse, varscan2
- CDH4 | c.426G>T p.L142= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV64650043, COSV64673683; called by muse, mutect2, varscan2
- DENND2D | c.636A>T p.S212= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV62958938; called by muse, mutect2, varscan2
- DNAH17 | c.1108C>T p.L370= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV67752419, COSV67758214; called by muse, mutect2, varscan2
- DSP | c.7962G>A p.Q2654= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs767539050, COSV60939176; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFHC1 | c.1239G>A p.L413= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV64136061; called by muse, mutect2, varscan2
- EGFLAM | c.2583A>G p.R861= (on ENST00000354891 / NM_001205301.2; = p.R853= on NM_152403.4) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV59298658; called by muse, mutect2, varscan2
- FAM13A | c.936A>G p.L312= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52000841; called by muse, mutect2, varscan2
- FKBP10 | c.897C>T p.D299= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs560280765, COSV58636152; called by muse, mutect2, varscan2
- FMNL2 | c.1131T>C p.D377= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV56493330; called by muse, mutect2, varscan2
- ITGA4 | c.1215C>T p.G405= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs754585299, COSV51999397; called by muse, mutect2, varscan2
- KLRC2 | c.312G>A p.P104= | Silent (SNP) | VAF 99/560 reads (18%) | catalogued as rs749002157, COSV67899763; called by muse, mutect2, varscan2
- LTBP2 | c.2640C>A p.P880= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV56206970; called by muse, mutect2, varscan2
- MUC4 | c.5274C>A p.A1758= | Silent (SNP) | VAF 42/258 reads (16%) | catalogued as COSV62143841; called by muse, varscan2
- NKG7 | c.297T>C p.F99= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52467389; called by muse, mutect2, varscan2
- NLGN4X | c.1143C>T p.D381= | Silent (SNP) | VAF 64/110 reads (58%) | catalogued as rs764507720, COSV52042984, COSV99319681; called by muse, mutect2, varscan2
- OR14A2 | c.741T>A p.T247= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as COSV63573521; called by muse, mutect2, varscan2
- PARP2 | c.831A>C p.A277= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV51638642; called by muse, mutect2, varscan2
- PEG3 | c.3351G>A p.V1117= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV55630642; called by muse, mutect2, varscan2
- PLA2G4F | c.1980A>T p.T660= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1418223261, COSV51826357; called by muse, mutect2, varscan2
- PLCB2 | c.2091C>T p.R697= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV53032644; called by muse, mutect2, varscan2
- PPP5C | c.165C>T p.I55= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs374930457; called by muse, mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs147089589; called by muse, mutect2, varscan2
- RRM2B | c.390C>A p.I130= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV52566401; called by muse, mutect2, varscan2
- SPATA18 | c.1389T>C p.A463= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs752564973, COSV54643665; called by muse, mutect2, varscan2
- STEAP2 | c.111A>G p.G37= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as COSV55290555; called by muse, mutect2, varscan2
- STXBP1 | c.732C>A p.L244= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV64812799; called by muse, mutect2, varscan2
- TEX11 | c.1002C>T p.P334= (on ENST00000344304; = p.P319= on NM_031276.3) | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as COSV60229225; called by muse, mutect2, varscan2
- TMPRSS13 | c.777A>G p.S259= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs758103334, COSV70626155; called by muse, mutect2, varscan2
- TMPRSS15 | c.2739T>G p.A913= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.2922C>G p.S974= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV51954552, COSV99511286; called by muse, mutect2, varscan2
- UNC5C | c.1251G>T p.S417= | Silent (SNP) | VAF 70/190 reads (37%) | catalogued as COSV71659046; called by muse, mutect2, varscan2
- VAX1 | c.249G>A p.K83= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs567659626; called by muse, mutect2, varscan2
- CCDC144NL | n.677del | RNA (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- COLCA2 | chr11:111296194 C>G | 5'Flank (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- EP400P1 | n.455_462del | RNA (DEL) | VAF 37/121 reads (31%) | called by mutect2, pindel, varscan2
- FOXL2 | c.-95T>A | 5'UTR (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100374948; called by muse, mutect2
- IFT172 | c.40-693T>A | Intron (SNP) | VAF 36/129 reads (28%) | catalogued as COSV99563701; called by muse, mutect2, varscan2
- KRTAP20-2 | c.*98A>G | 3'UTR (SNP) | VAF 54/152 reads (36%) | called by muse, mutect2, varscan2
- LRRC52 | c.*1T>A | 3'UTR (SNP) | VAF 53/118 reads (45%) | catalogued as COSV54231826; called by muse, mutect2, varscan2
- MFAP2 | c.154+25A>G | Intron (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- PIGM | c.-122T>C | 5'UTR (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100928081; called by muse, mutect2, varscan2
- SERTM1 | c.*2244C>A | 3'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100171555; called by muse, mutect2, varscan2
- SPRR3 | c.*99C>A | 3'UTR (SNP) | VAF 18/205 reads (9%) | catalogued as COSV99768834; called by muse, mutect2
- TRIM36 | c.64-7396C>A | Intron (SNP) | VAF 14/122 reads (11%) | catalogued as COSV56689663; called by muse, mutect2, varscan2
- ZNF789 | c.24+11C>T | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as rs1347140453; called by muse, mutect2, varscan2
